Somatic mutation profile of tumor specimen TCGA-VS-A94W-01A (aliquot TCGA-VS-A94W-01A-12D-A37N-09) from TCGA case TCGA-VS-A94W, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 39.4 years (14,399 days).
Specimen TCGA-VS-A94W-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 86f10cbe-37f0-404f-9347-1b1d6db611d9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VS-A94W-10A (Blood Derived Normal), aliquot TCGA-VS-A94W-10A-01D-A37N-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d2eea928-1213-4e7c-876c-69ced0993230

The open-access MAF lists 68 somatic variants for this specimen: 53 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 14, Nonsense Mutation 7, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MPDZ | c.3211C>T p.R1071* | Nonsense Mutation (SNP) | VAF 26/467 reads (6%) | catalogued as rs376078512; ClinVar: pathogenic; called by muse, mutect2
- A4GALT | c.957G>T p.K319N | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.681); catalogued as COSV99966673; called by muse, mutect2, varscan2
- ALCAM | c.329G>C p.R110T | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.864); catalogued as COSV100064978, COSV60254019; called by muse, mutect2, varscan2
- ASIC2 | c.1505C>T p.T502M | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as rs201100877; called by muse, mutect2
- ATL3 | c.1450C>T p.L484F | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.349); catalogued as COSV100219894; called by muse, mutect2, varscan2
- ATRX | c.6988C>T p.Q2330* | Nonsense Mutation (SNP) | VAF 15/53 reads (28%) | catalogued as COSV100970956; called by muse, mutect2, varscan2
- BRCA1 | c.4913A>T p.E1638V | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV100524401; called by muse, mutect2, varscan2
- CDH15 | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 6/132 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1225546069, COSV99228530; called by muse, mutect2
- CELSR1 | c.5660G>A p.C1887Y | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.274); catalogued as COSV99416725, COSV99418713; called by muse, mutect2, varscan2
- CFHR1 | c.809G>A p.R270Q | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.074); catalogued as rs368662175; called by muse, mutect2, varscan2
- CNIH3 | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.503); catalogued as rs1365117505, COSV99685948; called by muse, mutect2, varscan2
- COL20A1 | c.322C>T p.R108W | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs763041446, COSV58914171; called by muse, mutect2, varscan2
- CORO2A | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.158); catalogued as COSV59663848, COSV59664854; called by muse, mutect2, varscan2
- CRX | c.118C>T p.R40W | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs749738655, CM157887, COSV55759760; called by muse, mutect2, varscan2
- DMD | c.6927A>T p.L2309F | Missense Mutation (SNP) | VAF 37/123 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100627822; called by muse, mutect2, varscan2
- EYS | c.605G>A p.C202Y | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100676653; called by muse, mutect2, varscan2
- FAM71B | c.1537C>G p.Q513E | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV100262159, COSV57230875; called by muse, mutect2, varscan2
- GFOD2 | c.621G>T p.Q207H | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.099); catalogued as COSV99263588; called by muse, mutect2
- GTF3C1 | c.4852G>A p.E1618K | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV100649498; called by muse, mutect2, varscan2
- IFI27L2 | c.35G>A p.G12E | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs765630307, COSV99463107; called by muse, mutect2, varscan2
- JAKMIP1 | c.2419C>T p.R807W | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as rs376058279, COSV68956413; called by mutect2, varscan2
- KARS1 | c.689G>A p.R230K | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1306530636, COSV100094189; called by muse, mutect2, varscan2
- KIF22 | c.689G>A p.R230Q | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as rs775371597, COSV50714599; called by muse, mutect2, varscan2
- LRBA | c.2036C>T p.A679V | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV100841752; called by muse, mutect2, varscan2
- LRP1B | c.13292C>A p.P4431Q | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.997); catalogued as COSV101254757, COSV101256791; called by muse, mutect2, varscan2
- LRP2BP | c.718C>T p.R240C | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs770063174, COSV100145966; called by muse, mutect2, varscan2
- MSR1 | c.1145G>A p.R382H | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.09); catalogued as rs1028335673, COSV50526749; called by muse, mutect2, varscan2
- MUC5AC | c.14396G>A p.R4799H | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.165); catalogued as rs760524829, COSV100611480; called by muse, mutect2, varscan2
- NDFIP2 | c.872G>A p.G291E | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99519303; called by muse, mutect2
- OR2G6 | c.276G>A p.M92I | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100598211; called by muse, mutect2, varscan2
- OR4B1 | c.796G>T p.D266Y | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs765760170, COSV58883405; called by muse, mutect2, varscan2
- POLG2 | c.899T>C p.I300T | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV101604428; called by muse, mutect2, varscan2
- PSMD1 | c.2122C>T p.Q708* | Nonsense Mutation (SNP) | VAF 11/39 reads (28%) | catalogued as COSV100433681; called by muse, mutect2, varscan2
- PTPRZ1 | c.3016C>G p.L1006V | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.005); catalogued as rs11772668; called by muse, varscan2
- RBM25 | c.1352G>A p.R451Q | Missense Mutation (SNP) | VAF 35/63 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV99998792; called by muse, mutect2, varscan2
- RBM28 | c.1048G>C p.E350Q | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.012); catalogued as COSV99775761; called by muse, mutect2, varscan2
- RBSN | c.1225C>T p.R409* | Nonsense Mutation (SNP) | VAF 6/20 reads (30%) | catalogued as COSV99515334; called by muse, varscan2
- REEP5 | c.350A>T p.K117M | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99809907; called by muse, mutect2
- RGS6 | c.80G>A p.C27Y | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV100666408; called by muse, mutect2, varscan2
- RIMS1 | c.1909A>T p.K637* | Nonsense Mutation (SNP) | VAF 7/34 reads (21%) | catalogued as COSV99327756; called by muse, mutect2, varscan2
- RTN2 | c.1438C>G p.L480V | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.56); catalogued as COSV99839022; called by muse, mutect2, varscan2
- SBNO2 | c.2998C>T p.R1000W | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as rs773486482, COSV62322191; called by muse, mutect2, varscan2
- SLC6A19 | c.289C>T p.R97W | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58672964; called by muse, mutect2, varscan2
- SPIN3 | c.47C>T p.T16M | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.374); catalogued as COSV66529331; called by muse, mutect2, varscan2
- SPTB | c.560C>T p.T187M | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs184200762, COSV101072214; called by muse, mutect2, varscan2
- SSX2IP | c.1124C>T p.S375L | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.076); catalogued as COSV100642616; called by muse, mutect2, varscan2
- THSD1 | c.1216C>T p.Q406* | Nonsense Mutation (SNP) | VAF 3/18 reads (17%) | catalogued as COSV99318932; called by muse, mutect2
- TICRR | c.1802A>T p.D601V | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.812); catalogued as COSV99176753; called by muse, mutect2, varscan2
- TMEM132B | c.1467G>A p.M489I | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.077); catalogued as COSV100170016; called by muse, mutect2, varscan2
- TNC | c.3779G>A p.G1260E | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.981); catalogued as COSV60785191; called by muse, mutect2, varscan2
- ZC3H3 | c.86C>T p.P29L | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.459); catalogued as rs774760836, COSV99368043; called by muse, mutect2, varscan2
- ZNF761 | c.1230C>G p.Y410* | Nonsense Mutation (SNP) | VAF 10/86 reads (12%) | catalogued as COSV100483413; called by muse, mutect2, varscan2
- UBE4B | c.3229G>T p.A1077S (on ENST00000343090 / NM_001105562.3; = p.A948S on NM_006048.5) | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.026); called by muse, mutect2
- ACSL5 | c.1027T>C p.L343= (on ENST00000354273; = p.L399= on NM_016234.3) | Silent (SNP) | VAF 16/78 reads (21%) | catalogued as COSV100634640; called by muse, mutect2, varscan2
- ATP1A4 | c.435C>T p.S145= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as rs780624299, COSV100927579, COSV63625681; called by muse, mutect2, varscan2
- B4GALNT4 | c.2709G>A p.A903= | Silent (SNP) | VAF 19/73 reads (26%) | catalogued as rs1344779945, COSV100327659; called by muse, mutect2, varscan2
- C16orf46 | c.979C>T p.L327= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as COSV100215376, COSV100215454; called by muse, mutect2, varscan2
- CLASRP | c.126G>A p.Q42= | Silent (SNP) | VAF 41/84 reads (49%) | catalogued as rs751263482, COSV99673900; called by muse, mutect2, varscan2
- DBX2 | c.450G>A p.A150= | Silent (SNP) | VAF 27/90 reads (30%) | catalogued as rs372280888; called by muse, mutect2, varscan2
- FCGR1A | c.393G>C p.L131= | Silent (SNP) | VAF 17/93 reads (18%) | catalogued as COSV100977294; called by muse, mutect2, varscan2
- MAGEA10 | c.414G>A p.V138= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as COSV99726761; called by muse, mutect2, varscan2
- MYO7B | c.687C>T p.G229= | Silent (SNP) | VAF 23/84 reads (27%) | catalogued as rs377216470; called by muse, mutect2, varscan2
- PCDHA10 | c.168G>A p.A56= | Silent (SNP) | VAF 8/100 reads (8%) | catalogued as rs782147679, COSV56554916; called by muse, mutect2
- RD3 | c.510C>T p.S170= | Silent (SNP) | VAF 3/20 reads (15%) | catalogued as COSV65363011; called by muse, mutect2
- SIGLEC7 | c.450C>G p.P150= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as COSV99978777; called by mutect2, varscan2
- SPTAN1 | c.6639C>T p.H2213= | Silent (SNP) | VAF 84/165 reads (51%) | catalogued as rs372825476; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- TBX20 | c.1191G>A p.L397= | Silent (SNP) | VAF 20/60 reads (33%) | catalogued as rs769406588, COSV101282389; called by muse, mutect2, varscan2
- SSPOP | n.1818C>T | RNA (SNP) | VAF 13/68 reads (19%) | catalogued as COSV100022638; called by muse, mutect2, varscan2
